Surgical pathology report (de-identified scan), TCGA case TCGA-38-4632, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-4632-01A (Primary Tumor).

DIAGNOSIS

LUNG, LEFT UPPER LOBE, LOBECTOMY - ADENOCARCINOMA, POORLY DIFFERENTIATED, TUMOR SIZE 5.8 CM IN GREATEST DIMENSION, TUMOR EXTENDS TO BUT NOT THROUGH THE VISCERAL PLEURA WITH FIBRINOPURULENT AND GRANULATION TISSUE PLEURAL RESPONSE, SURGICAL MARGINS FREE OF TUMOR

- EXTENSIVE RECENT AND OLD HEMORRHAGE IN NON-TUMOROUS LUNG AROUND THE TUMOR

- METASTATIC ADENOCARCINOMA IN TWO OF SEVEN HILAR NODES FROM LOBECTOMY SPECIMEN

MEDIASTINAL LYMPH NODES, STATION 5, REMOVAL - NO TUMOR SEEN IN ONE LYMPH NODE (0/1), FOLLICULAR HYPERPLASIA AND HYALINIZED GRANULOMAS ALSO PRESENT

MEDIASTINAL LYMPH NODES, STATION 9, REMOVAL - NO TUMOR SEEN IN TWO LYMPH NODES (0/2), FOLLICULAR HYPERPLASIA AND HYALINIZED GRANULOMAS PRESENT

LYMPH NODES FROM PULMONARY FISSURE, BIOPSY - NO TUMOR SEEN IN THREE LYMPH NODES (0/3), FOLLICULAR HYPERPLASIA AND HYALINIZED GRANULOMAS PRESENT

MEDIASTINAL LYMPH NODE, STATION 7, BIOPSY - NO TUMOR SEEN IN ONE LYMPH NODE (0/1), FOLLICULAR HYPERPLASIA PRESENT

MEDIASTINAL LYMPH NODE, STATION 11, BIOPSY - NO TUMOR SEEN IN ONE LYMPH NODE (0/1), FOLLICULAR HYPERPLASIA PRESENT

Source: NCI Genomic Data Commons file 4912a8d4-4d6d-4a8b-84c4-74261b4b3cf1 (TCGA-38-4632.8A178633-5C59-47FE-B1CE-C15E03C66198.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).